Somatic mutation profile of tumor specimen TARGET-10-PARIBB-09A (aliquot TARGET-10-PARIBB-09A-01D) from TARGET case TARGET-10-PARIBB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.7 years (4,268 days).
Specimen TARGET-10-PARIBB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce659fca-1258-44ea-b6c1-881b23351644.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARIBB-10A (Blood Derived Normal), aliquot TARGET-10-PARIBB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf37db10-bbf9-4d62-90c7-9d3dca48296d

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 2, Nonsense Mutation 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SGPL1 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 31/113 reads (27%) | catalogued as rs746887949, COSV100940349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1782C>A p.C594* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs755974145, COSV60106156, COSV60125454; called by muse, mutect2, varscan2
- CMAS | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as rs756644966; called by muse, mutect2, varscan2
- DSCAML1 | c.607G>A p.V203I (on ENST00000321322; = p.V143I on NM_020693.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs554359582, COSV100357110, COSV58396444; called by muse, mutect2, varscan2
- KIAA1217 | c.4238C>T p.T1413M | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763517809; called by muse, mutect2
- MEP1A | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762345708; called by muse, mutect2, varscan2
- PCYT1B | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV63264889; called by muse, mutect2
- DNAH9 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- HUWE1 | c.5223A>C p.K1741N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDHB1 | c.1699C>A p.Q567K | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PPM1H | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TRPV3 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- UGGT2 | c.1355A>T p.N452I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DSCAM | c.234C>T p.N78= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs770298655, COSV101258638, COSV68626120; called by muse, mutect2, varscan2
- STARD8 | c.3039C>A p.T1013= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99367680; called by muse, mutect2, varscan2
- TBC1D31 | c.1932A>G p.R644= | Silent (SNP) | VAF 57/100 reads (57%) | called by muse, mutect2, varscan2
- HDGFL1 | c.*73G>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- HYDIN2 | n.7044G>A | RNA (SNP) | VAF 14/27 reads (52%) | catalogued as rs1250987082; called by muse, mutect2, varscan2
- PRPF38A | c.291-218A>G | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- RPS4X | c.361-26T>C | Intron (SNP) | VAF 91/155 reads (59%) | called by muse, mutect2, varscan2
